Somatic mutation profile of tumor specimen C3N-00732-01 (aliquot CPT0089600009) from CPTAC case C3N-00732, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 56.6 years (20,659 days).
Specimen C3N-00732-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb9f5536-82ef-4f67-a2a0-10b1db9b3de2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00732-31 (Blood Derived Normal), aliquot CPT0091360002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/033630d5-1c99-4380-881e-b3500f0083ff

The open-access MAF lists 74 somatic variants for this specimen: 48 protein-altering or splice-affecting, 20 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 20, Intron 4, Nonsense Mutation 3, In Frame Del 2, Frame Shift Ins 2, Splice Site 1, 5'UTR 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCND1 | c.859C>A p.P287T | Missense Mutation (SNP) | VAF 25/86 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57119846, COSV57120106, COSV57120715; called by muse, varscan2
- CTNNB1 | c.109T>C p.S37P | Missense Mutation (SNP) | VAF 208/638 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs121913228, COSV62688488, COSV62688537, COSV62706597; ClinVar: likely pathogenic; called by muse, varscan2
- PIK3CA | c.3127A>G p.M1043V | Missense Mutation (SNP) | VAF 151/206 reads (73%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1057519936, COSV55879858, COSV55890961; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.2098A>G p.K700E | Missense Mutation (SNP) | VAF 9/102 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs559063155, COSV59205318, COSV59216586; ClinVar: likely pathogenic; called by muse, mutect2
- CDH11 | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 90/224 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.271); catalogued as rs754745285, COSV51762311; called by muse, mutect2, varscan2
- CNGB3 | c.1579-1G>C p.X527_splice | Splice Site (SNP) | VAF 16/406 reads (4%) | catalogued as CS1413415; called by muse, mutect2
- GDF5 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as rs760571449, COSV65502407; called by muse, mutect2, varscan2
- GMFB | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 111/340 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as rs1452327858, COSV100794597; called by muse, mutect2, varscan2
- LOXL2 | c.1318G>A p.G440S | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778460550, COSV66690343, COSV66693478; called by muse, mutect2, varscan2
- LRIT2 | c.1470C>A p.C490* | Nonsense Mutation (SNP) | VAF 22/76 reads (29%) | catalogued as rs1564670947, COSV60561818; called by muse, mutect2
- MACF1 | c.3772C>T p.R1258* | Nonsense Mutation (SNP) | VAF 7/178 reads (4%) | catalogued as rs1250062910; called by muse, mutect2
- MYBBP1A | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 78/266 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.893); catalogued as rs770634004, COSV99626223; called by muse, mutect2, varscan2
- MYH11 | c.3560C>T p.T1187M | Missense Mutation (SNP) | VAF 164/542 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); catalogued as rs552818350; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NALCN | c.4048G>A p.A1350T | Missense Mutation (SNP) | VAF 81/254 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51947422; called by muse, mutect2, varscan2
- OLFML2B | c.1735C>T p.R579C | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54194598; called by muse, mutect2, varscan2
- OR5H2 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 90/245 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as rs201934750; called by muse, mutect2, varscan2
- PARS2 | c.1216G>A p.G406R | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.866); catalogued as rs759228236, COSV64883356; called by muse, mutect2, varscan2
- PTGS1 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 77/291 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs10306140; called by muse, mutect2, varscan2
- RPRD2 | c.712_714del p.K238del | In Frame Del (DEL) | VAF 46/135 reads (34%) | catalogued as rs1361172280; called by pindel, varscan2
- SLC13A4 | c.678C>A p.N226K | Missense Mutation (SNP) | VAF 86/266 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1038541086; called by muse, mutect2, varscan2
- SLC1A6 | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 72/179 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.34); catalogued as rs996260256, COSV55667680; called by muse, mutect2, varscan2
- SMARCAL1 | c.1976G>A p.R659H | Missense Mutation (SNP) | VAF 177/611 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs568131335; called by muse, mutect2, varscan2
- TRIM49B | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 208/615 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.213); catalogued as rs747715650; called by muse, mutect2, varscan2
- TTN | c.36244G>A p.G12082S (on ENST00000591111; = p.G4658S on NM_003319.4) | Missense Mutation (SNP) | VAF 141/396 reads (36%) | PolyPhen probably damaging (0.999); catalogued as rs188301588; called by muse, mutect2, varscan2
- WAS | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 168/502 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1215457658, COSV64996832; called by muse, mutect2, varscan2
- WNT4 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 233/694 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.225); catalogued as rs759336061; called by muse, mutect2, varscan2
- ANO7 | c.1799_1801del p.Y600del (on ENST00000274979; = p.Y546del on NM_001370694.2) | In Frame Del (DEL) | VAF 91/249 reads (37%) | called by mutect2, pindel, varscan2
- CPA5 | c.291G>C p.E97D | Missense Mutation (SNP) | VAF 69/205 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DENND4C | c.4687G>T p.D1563Y (on ENST00000434457 / NM_001330640.2; = p.D1514Y on NM_017925.7) | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- EMC2 | c.20T>G p.L7R | Missense Mutation (SNP) | VAF 81/287 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- FAM120C | c.1124A>T p.D375V | Missense Mutation (SNP) | VAF 123/423 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGLV7-43 | c.116_117del p.L39Hfs*32 | Frame Shift Del (DEL) | VAF 52/212 reads (25%) | called by pindel, varscan2
- KLHL5 | c.1584G>T p.L528F | Missense Mutation (SNP) | VAF 152/467 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- MAB21L1 | c.844T>C p.C282R | Missense Mutation (SNP) | VAF 110/344 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- MED24 | c.2296G>T p.E766* | Nonsense Mutation (SNP) | VAF 182/267 reads (68%) | called by muse, mutect2, varscan2
- MRPL43 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 88/495 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- NAT16 | c.703G>T p.D235Y | Missense Mutation (SNP) | VAF 219/600 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- NBEA | c.7720C>A p.Q2574K | Missense Mutation (SNP) | VAF 72/181 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- NLGN4X | c.157G>C p.G53R | Missense Mutation (SNP) | VAF 214/642 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PABPN1 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- PCNX2 | c.3692T>A p.M1231K | Missense Mutation (SNP) | VAF 18/251 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2
- PRG2 | c.218C>A p.A73D | Missense Mutation (SNP) | VAF 226/663 reads (34%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- PRR14L | c.2533dup p.S845Kfs*4 | Frame Shift Ins (INS) | VAF 72/252 reads (29%) | called by mutect2, pindel, varscan2
- RAD54L2 | c.3178T>G p.Y1060D | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TARBP2 | c.1010G>C p.C337S (on ENST00000266987 / NM_134323.2; = p.C316S on NM_004178.4) | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- TRRAP | c.1889A>T p.E630V | Missense Mutation (SNP) | VAF 116/380 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); called by muse, varscan2
- WDR87 | c.5778dup p.Q1927Tfs*32 | Frame Shift Ins (INS) | VAF 95/328 reads (29%) | called by mutect2, pindel, varscan2
- WNK3 | c.2488G>T p.V830F | Missense Mutation (SNP) | VAF 19/268 reads (7%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.08); called by muse, mutect2
- ABCA4 | c.5928C>T p.A1976= | Silent (SNP) | VAF 34/629 reads (5%) | catalogued as rs376767237; called by muse, mutect2
- AKAP6 | c.4476G>A p.A1492= | Silent (SNP) | VAF 78/231 reads (34%) | catalogued as rs367628739; called by muse, mutect2, varscan2
- CBY3 | c.633G>C p.T211= | Silent (SNP) | VAF 58/195 reads (30%) | catalogued as rs369839116; called by muse, mutect2, varscan2
- CDYL2 | c.252G>A p.P84= | Silent (SNP) | VAF 151/476 reads (32%) | catalogued as rs1036863414, COSV101629519, COSV73647999; called by muse, varscan2
- CENPL | c.150C>G p.P50= | Silent (SNP) | VAF 48/128 reads (38%) | called by muse, mutect2, varscan2
- CLTRN | c.447G>T p.V149= | Silent (SNP) | VAF 16/460 reads (3%) | called by muse, mutect2
- DHRS12 | c.774C>T p.G258= (on ENST00000444610 / NM_001377930.1; = p.G209= on NM_024705.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 60/161 reads (37%) | catalogued as rs1270899613; called by muse, mutect2, varscan2
- EDA | c.858A>G p.L286= | Silent (SNP) | VAF 33/610 reads (5%) | called by muse, mutect2
- KATNB1 | c.708C>T p.S236= | Silent (SNP) | VAF 72/228 reads (32%) | catalogued as rs781979251; called by muse, mutect2
- KLK14 | c.558C>T p.G186= | Silent (SNP) | VAF 18/262 reads (7%) | called by muse, mutect2
- KRT1 | c.1782C>T p.G594= | Silent (SNP) | VAF 161/454 reads (35%) | catalogued as rs1161223903, COSV52864853; called by muse, mutect2, varscan2
- MAMLD1 | c.1656G>A p.P552= | Silent (SNP) | VAF 206/586 reads (35%) | catalogued as rs1460185195, COSV53374489; called by muse, varscan2
- MATR3 | c.1029C>T p.F343= | Silent (SNP) | VAF 145/449 reads (32%) | called by muse, mutect2, varscan2
- MN1 | c.1713C>T p.R571= | Silent (SNP) | VAF 72/214 reads (34%) | called by muse, mutect2, varscan2
- PCDHA12 | c.2073G>A p.A691= | Silent (SNP) | VAF 151/429 reads (35%) | catalogued as COSV56485969; called by muse, mutect2, varscan2
- POTEC | c.240G>A p.V80= | Silent (SNP) | VAF 221/710 reads (31%) | catalogued as COSV62802031; called by muse, mutect2, varscan2
- REV1 | c.1530T>C p.S510= | Silent (SNP) | VAF 12/219 reads (5%) | catalogued as rs1559332818; called by muse, mutect2
- RNF213 | c.5115G>A p.T1705= | Silent (SNP) | VAF 378/559 reads (68%) | catalogued as rs368266183; called by muse, mutect2, varscan2
- TAFA2 | c.354T>C p.C118= | Silent (SNP) | VAF 14/166 reads (8%) | called by muse, mutect2
- TSSK4 | c.699G>A p.V233= | Silent (SNP) | VAF 91/284 reads (32%) | called by muse, mutect2, varscan2
- AC004551.1 | n.354-23240T>C | Intron (SNP) | VAF 87/278 reads (31%) | catalogued as COSV104440927; called by muse, mutect2, varscan2
- COL1A2 | c.2349+14A>G | Intron (SNP) | VAF 159/487 reads (33%) | catalogued as rs747618970; called by muse, mutect2, varscan2
- COL9A3 | c.147+177G>T | Intron (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2, varscan2
- GREM1 | c.-47G>A | 5'UTR (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2
- LINC01580 | chr15:93899244 C>T | 5'Flank (SNP) | VAF 61/186 reads (33%) | catalogued as rs576274944; called by muse, mutect2, varscan2
- TSC22D4 | c.930-369dup | Intron (INS) | VAF 52/162 reads (32%) | catalogued as rs760307258; called by mutect2, varscan2
